Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3CB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3CB-06A (Metastatic).

DIAGNOSIS

Patient ID

ICD-0-3

Melanoma, NOS 8720/3

site: lymph nodes, axillary

C 77.3

hw 10/3/11
hw

(A) LEFT AXILLARY CONTENTS:

METASTATIC MELANOMA INVOLVING ONE OF TWENTY-ONE LYMPH NODES. (1/21)

TUMOR DEPOSIT SIZE, 40.0 X 30.0 MM.

EXTRACAPSULAR EXTENSION PRESENT.

Skin with healing surgical wound.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) LEFT AXILLARY CONTENTS - A non-oriented irregular fragment of adipose tissue (14.0 x 11.0 x 5.0 cm). Attached to the specimen an ellipse of skin (13.0 x 1.5 cm). On the surface of the skin a healed scar (6.0 cm in length) is present.

The specimen is serially sectioned and biopsy site is present (4.0 x 3.0 cm). In addition to that, 25 lymph nodes were identified, ranging in size from (0.2 x 0.2 x 0.2 to 4.0 x 3.0 x 2.5 cm).

SECTION CODE: A1, representative sections of the skin; A2, representative sections of the skin and biopsy site; A3, four lymph nodes; A4, four lymph nodes; A5, three lymph nodes; A6, three lymph nodes; A7, two lymph nodes; A8, two lymph nodes; A9, two lymph nodes; A10, two lymph nodes; A11, A12, one lymph node, serially sectioned; A13-A17, one lymph node, serially sectioned; A18, A19, remainder of the largest lymph node.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

T-02420, T-C4710, M-87206, M-78060

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Released by:

-----END OF REPORT-----

hw 10/3/11

Source: NCI Genomic Data Commons file 7d023ede-fd52-4be8-8998-9114949aa209 (TCGA-D3-A3CB.5C8072EF-06A4-4E06-83EA-295E7D169107.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).